Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4852, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4852-01A (Primary Tumor).

TCGA-B0-4852

FINAL DIAGNOSIS:

KIDNEY, LEFT, RADICAL LAPAROSCOPIC NEPHRECTOMY—

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. THE CARCINOMA MEASURES 8.8 CM IN GREATEST DIMENSION AND HAS A FUHRMAN GRADE OF 2 OUT OF 4.
- C. THE TUMOR IS CONFINED TO THE KIDNEY AND DOES NOT EXTEND INTO THE PERINEPHRIC FAT.
- D. ALL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION.
- F. PATHOLOGIC STAGE T2NxMx.
- G. UNINVOLVED RENAL PARENCHYMA UNREMARKABLE.

Source: NCI Genomic Data Commons file 6d8f043e-d5ea-4a25-8fdc-6333b016de05 (TCGA-B0-4852.562F6883-15AE-4222-A680-6C0D9D63B3BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).